Somatic mutation profile of tumor specimen TCGA-DD-A4NJ-01A (aliquot TCGA-DD-A4NJ-01A-11D-A27I-10) from TCGA case TCGA-DD-A4NJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 54.7 years (19,964 days).
Specimen TCGA-DD-A4NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d8b64e7-d52e-441b-9621-8fbf93b384d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NJ-10A (Blood Derived Normal), aliquot TCGA-DD-A4NJ-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1d4bb3d-a49a-46a4-84c1-0daf42827a05

The open-access MAF lists 86 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Intron 1, 5'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3581G>A p.G1194D | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs1553509744, COSV58592784; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64110018; called by muse, mutect2, varscan2
- ANGPT4 | c.951+2T>G p.X317_splice | Splice Site (SNP) | VAF 50/140 reads (36%) | catalogued as COSV67922202; called by muse, mutect2, varscan2
- ANKFN1 | c.2047C>T p.L683F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV59452735; called by muse, mutect2, varscan2
- ASB10 | c.587G>A p.C196Y (on ENST00000420175 / NM_001142459.2; = p.C181Y on NM_080871.4) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51997987; called by muse, mutect2, varscan2
- ASTL | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60904782; called by muse, mutect2, varscan2
- CAND2 | c.2998G>T p.D1000Y (on ENST00000456430 / NM_001162499.2; = p.D907Y on NM_012298.3) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99928927; called by muse, mutect2, varscan2
- CD101 | c.508G>C p.A170P | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV56719174; called by muse, mutect2, varscan2
- CDH3 | c.1654C>A p.Q552K | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV50562447; called by muse, mutect2, varscan2
- CFAP300 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1565399341, COSV71570873; called by muse, mutect2, varscan2
- CLCNKB | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 59/510 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs1411519836, COSV65161171; called by muse, mutect2, varscan2
- DST | c.3651A>T p.Q1217H (on ENST00000361203 / NM_001374722.1; = p.Q891H on NM_001723.6) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.799); catalogued as COSV55025677; called by muse, mutect2, varscan2
- EBF3 | c.988T>C p.Y330H (on ENST00000355311 / NM_001375392.1; = p.Y321H on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62477543; called by muse, mutect2, varscan2
- FBXL20 | c.934-1G>T p.X312_splice | Splice Site (SNP) | VAF 33/76 reads (43%) | catalogued as COSV52901051; called by muse, mutect2, varscan2
- FLYWCH2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV53559215, COSV99567211; called by muse, mutect2, varscan2
- FZD2 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59529513; called by muse, mutect2
- GLI2 | c.4223G>T p.G1408V (on ENST00000361492 / NM_001374353.1; = p.G1425V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV58046023; called by muse, mutect2, varscan2
- HTR3C | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs556123764, COSV100570557; called by muse, mutect2, varscan2
- IL36B | c.144T>A p.C48* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV52087530; called by muse, mutect2, varscan2
- IQSEC3 | c.2477T>A p.L826Q (on ENST00000538872 / NM_001170738.2; = p.L523Q on NM_015232.1) | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV58287237; called by muse, mutect2, varscan2
- IRS4 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64534776; called by muse, mutect2, varscan2
- IRX1 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57360727; called by muse, mutect2, varscan2
- KIF26A | c.3502A>C p.S1168R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV100181022; called by muse, mutect2
- KIF26A | c.3503G>T p.S1168I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100181023; called by muse, mutect2
- KRT1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV52867901; called by muse, mutect2, varscan2
- LPIN3 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60037341; called by muse, mutect2, varscan2
- MTAP | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as rs368718537, COSV66478082; called by muse, mutect2, varscan2
- NF1 | c.2243T>G p.M748R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62210274; called by muse, mutect2, varscan2
- NLGN4X | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 125/558 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52003073; called by muse, mutect2, varscan2
- NLRP9 | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60465390; called by muse, mutect2, varscan2
- NRXN3 | c.3043T>A p.F1015I (on ENST00000335750 / NM_001330195.2; = p.F642I on NM_004796.6) | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59773994; called by muse, mutect2, varscan2
- OR6C75 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV58552431; called by muse, mutect2, varscan2
- PAX2 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1022509510, CD992538, COSV62291971; called by muse, mutect2, varscan2
- PCDH18 | c.2469C>A p.H823Q | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.301); catalogued as COSV61270005; called by muse, mutect2, varscan2
- PEG10 | c.250G>A p.E84K (on ENST00000482108 / NM_001040152.2; = p.E118K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV71788440; called by muse, mutect2, varscan2
- PFKFB1 | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 64/222 reads (29%) | PolyPhen probably damaging (0.999); catalogued as COSV66628864; called by muse, mutect2, varscan2
- PIK3CD | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.356); catalogued as COSV63129430; called by muse, mutect2, varscan2
- PLXNB3 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV62799328; called by muse, mutect2
- POC1B | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs111514387, COSV57966746; called by muse, mutect2, varscan2
- PYHIN1 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63723132; called by muse, mutect2, varscan2
- RB1 | c.946A>T p.N316Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV57315027; called by muse, mutect2, varscan2
- RB1 | c.1332G>A p.Q444= | Splice Region (SNP) | VAF 19/38 reads (50%) | catalogued as CS004738, CS081960, COSV57310134, COSV57315055; called by muse, mutect2, varscan2
- ROS1 | c.1799T>G p.L600* | Nonsense Mutation (SNP) | VAF 41/73 reads (56%) | catalogued as COSV63857868; called by muse, mutect2, varscan2
- RYR1 | c.10824G>T p.Q3608H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62103010; called by muse, mutect2, varscan2
- SHANK2 | c.2128A>T p.N710Y | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53607643; called by muse, mutect2, varscan2
- SLC45A4 | c.430G>A p.G144S (on ENST00000517878 / NM_001286646.2; = p.G93S on NM_001080431.2) | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.518); catalogued as rs1316871815, COSV50147208, COSV99196822; called by muse, mutect2, varscan2
- SNW1 | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55055345; called by muse, mutect2, varscan2
- SPEN | c.9127A>G p.S3043G | Missense Mutation (SNP) | VAF 146/732 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.189); catalogued as COSV65364547; called by muse, mutect2, varscan2
- STMN3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1484691556, COSV64246959; called by muse, mutect2, varscan2
- SUOX | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1325574553, COSV56269796; called by muse, mutect2, varscan2
- SYT5 | c.512C>G p.P171R | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62830815; called by muse, mutect2, varscan2
- TCAIM | c.1195T>A p.W399R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.316); catalogued as COSV61241560; called by muse, mutect2, varscan2
- TMC2 | c.1487A>T p.Y496F | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62655485; called by muse, mutect2, varscan2
- TMPRSS3 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1255143070, COSV52304999; called by muse, mutect2, varscan2
- TTC3 | c.4201G>A p.A1401T | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as COSV61293175; called by muse, mutect2, varscan2
- TTN | c.81533A>G p.D27178G (on ENST00000591111; = p.D19754G on NM_003319.4) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | PolyPhen probably damaging (0.998); catalogued as COSV60181087; called by muse, mutect2, varscan2
- UBR5 | c.2338C>G p.Q780E | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1212222560, COSV55293021; called by muse, mutect2, varscan2
- UEVLD | c.616A>C p.I206L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV57875731; called by muse, mutect2, varscan2
- ZBTB11 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs370264120; called by muse, mutect2, varscan2
- ZFYVE16 | c.1483T>G p.C495G | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62016406; called by muse, mutect2
- C1QTNF3 | c.539_549del p.V180Afs*13 | Frame Shift Del (DEL) | VAF 18/221 reads (8%) | called by mutect2, pindel
- DNAJB14 | c.378dup p.A127Sfs*3 | Frame Shift Ins (INS) | VAF 41/160 reads (26%) | called by mutect2, pindel, varscan2
- HPX | c.956_957del p.Y319Sfs*82 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.821_843del p.K274Rfs*25 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- HYDIN | c.13940A>G p.Q4647R | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, varscan2
- ADAMTS17 | c.2169C>T p.N723= | Silent (SNP) | VAF 135/283 reads (48%) | catalogued as rs368641530; called by muse, mutect2, varscan2
- ADCY8 | c.1365C>T p.C455= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as COSV53915781; called by muse, mutect2, varscan2
- ADGRE2 | c.507C>A p.S169= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as COSV59693078, COSV59694836; called by muse, mutect2, varscan2
- APCDD1 | c.81C>T p.L27= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV62372793; called by muse, mutect2, varscan2
- CAND2 | c.2997G>C p.S999= (on ENST00000456430 / NM_001162499.2; = p.S906= on NM_012298.3) | Silent (SNP) | VAF 46/176 reads (26%) | catalogued as COSV99928923; called by muse, mutect2, varscan2
- CCDC88C | c.1977G>A p.E659= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV66239495; called by muse, mutect2, varscan2
- CD200 | c.657T>A p.S219= (on ENST00000473539 / NM_001004196.3; = p.S194= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as COSV59863873; called by muse, mutect2
- CIDEC | c.219T>C p.T73= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV61062168; called by muse, mutect2, varscan2
- CNTN5 | c.840C>T p.V280= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as COSV54330591; called by muse, mutect2, varscan2
- FCGBP | c.7071G>C p.L2357= | Silent (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- HTR3C | c.1086C>A p.P362= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100570558; called by muse, mutect2, varscan2
- KCNK13 | c.1170G>T p.G390= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV56414750, COSV99965513; called by muse, mutect2, varscan2
- PCDHAC2 | c.1674A>G p.P558= | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as COSV53858880; called by muse, mutect2, varscan2
- PHACTR3 | c.1545G>A p.R515= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as COSV100733263, COSV63030899; called by muse, mutect2, varscan2
- PHF2 | c.2431C>T p.L811= | Silent (SNP) | VAF 76/222 reads (34%) | catalogued as COSV63682179; called by muse, mutect2, varscan2
- PRELID1 | c.429C>G p.V143= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV57463663; called by muse, mutect2, varscan2
- SLC20A1 | c.1230A>G p.K410= | Silent (SNP) | VAF 85/260 reads (33%) | catalogued as COSV55612099; called by muse, mutect2, varscan2
- THOP1 | c.235A>C p.R79= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV57019547; called by muse, mutect2, varscan2
- MGAT4B | c.1510+18G>T | Intron (SNP) | VAF 26/118 reads (22%) | catalogued as COSV52978455; called by muse, mutect2, varscan2
- NFRKB | c.-3A>G | 5'UTR (SNP) | VAF 23/165 reads (14%) | catalogued as COSV58759078; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23166324 A>G | 3'Flank (SNP) | VAF 14/224 reads (6%) | catalogued as rs1466975881; called by muse, mutect2
